Gene-level copy-number profile of tumor specimen TCGA-G2-AA3F-01A from TCGA case TCGA-G2-AA3F, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,457 days).
Specimen TCGA-G2-AA3F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.afa87960-ccb3-42d5-a403-6a77b86e9a59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-AA3F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ab00843c-0dc8-4819-a70c-69559871bc20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 6,415; copy number 3: 22,533; copy number 4: 24,190; copy number 5: 2,914; copy number 6: 2,548; copy number 7: 736; copy number 8: 325; copy number 9: 18; copy number 10: 35; copy number 11: 26; copy number 15: 46; copy number 17: 24; copy number 27: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-AA3F-01A-12D-A42D-01): tumor purity 0.68, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 150 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:106,697,331–108,687,246, 35 genes, copy number 10 (within-gene range 7–10): EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1, GACAT1, RGPD4-AS1, RGPD4, AC009963.2, AC009963.1, RPL22P8, SRSF3P5, SLC5A7, LINC01593, ACTP1, LINC01594, SETD6P1, SULT1C3, WASF1P1, SULT1C2, SULT1C2P2, SULT1C2P1, GMCL1P2, SULT1C4, SMIM12P1, GCC2, GCC2-AS1, LIMS1.
- chr6:20,401,879–20,493,714, 1 gene, copy number 11 (within-gene range 6–11): E2F3.
- chr6:20,437,821–23,404,132, 28 genes, copy number 11–27: E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1.
- chr8:99,873,200–102,412,759, 68 genes, copy number 15–17 (broad region; genes not listed).
- chr10:8,619,933–10,462,361, 18 genes, copy number 9: CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
